HCMI case HCM-CSHL-0062-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b3b1f24-419e-4043-82be-2bd41268bb0e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,784 days); AJCC staging edition: 8th; AJCC clinical stage: Stage I; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 13 days.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 88, day 365.

Molecular and laboratory tests
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps / Diverticulosis.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 13 days; Days to risk factor: 13 days; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 47.6 kg; Height: 154.9 cm; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0062-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0062-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 7.
  Slide HCM-CSHL-0062-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 7.
- Sample HCM-CSHL-0062-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0062-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
